Surgical pathology report (de-identified scan), TCGA case TCGA-19-5953, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Case Western, specimen TCGA-19-5953-01B (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

FINAL DIAGNOSIS

TCGA-19-5953

A.-D. RIGHT FRONTAL LOBE RANGE, MASS, BIOPSIES AND REMOVAL:

-- GLIOBLASTOMA MULTIFORME DEMONSTRATING PROMINENT SPINDLE CELL DIFFERENTIATION ("GLIOSARCOMA", WHO GRADE IV).

E. SPECIMEN LABELED SUPERFICIAL TUMOR, REMOVAL:

-- GLIOSARCOMA (WHO GRADE IV).

Electronically Signed Out By

By the signature on this report, the individual or group listed as making the Final Interpretation/Diagnosis certifies that they have reviewed this case.

Intraoperative Consultation:

A & B: Touch Imprint: Consistent with tumefactive demyelination.

C: Touch Imprint: Glioma blastoma.

Clinical History:

High grade glioma. Right Brain high grade glioma (E) Right Brain high grade glioma

Specimens Submitted As:

A:RIGHT FRONTAL BRAIN MASS

B:RIGHT FRONTAL BRAIN MASS

C:RIGHT FRONTAL BRAIN MASS

D:(R) BRAIN TUMOR

E:SUPERFICIAL TUMOR

Gross Description:

A: Received fresh for intraoperative consultation, labelled with the patient's name and hospital number, is a 0.5 x 0.5 x 0.3 cm aggregate of soft, tan-white tissue. Touch imprint is performed. A portion of the specimen is submitted for frozen. The specimen is submitted entirely in two cassettes.

B: Received fresh for intraoperative consultation, labelled with the patient's name and hospital number, is a 1.2 x 0.6 x 0.3 cm aggregate of soft, tan-white to red-tan soft tissue. Touch imprint is performed. A portion of the specimen is submitted for frozen section. The specimen is submitted entirely in two cassettes.

C: Received fresh for intraoperative consultation, labelled with the patient's name and hospital number, is a 1.4 x 0.5 x 0.3 cm aggregate of soft, tan-white to red-tan tissue. Touch imprint is performed. A portion of the specimen for frozen section. The specimen is submitted entirely in two cassettes.

D: Received fresh, post fixed in formalin, labeled with the patient's name and number, and "deep tumor for permanent", are multiple irregular, pink-tan, soft, cerebriform tissue fragments measuring in aggregate 4.5 x 3.8 x 1.5 cm. Submitted entirely in four cassettes.

[page 2 of 2]
E: Received fresh, post fixed in formalin, labeled with the patient's name and number, and "superficial perm", are multiple irregular, pink tan, soft tissue fragments measuring in aggregate 2.3 x 0.8 x 0.4 cm. Submitted in toto in one cassette.

Summary of Cassettes:

A	1FS	representative soft tissue
	2	remainder of specimen
B	1FS	representative soft tissue
	2	remainder of specimen
C	1FS	representative soft tissue
	2	remainder of specimen

Source: NCI Genomic Data Commons file c0bc2f74-6815-4337-8079-7f9fcaadef87 (TCGA-19-5953.3C12DDBB-84F3-46EE-A68D-51B82B8397A9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).